MMRF case MMRF_2580 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/607b4658-b81e-4190-a9a5-8bc3536e20e0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.4 years (29,358 days); ISS stage: I; Days to last known disease status: 616 days (1.7 years); Days to last follow up: 616 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23 (ECOG 1): M Protein 3.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 39 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 3.4 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.61 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.75 mmol/L; Albumin 40 g/L; Total Protein 9.2 g/dL; Glucose 6.05 mmol/L; C-Reactive Protein 0.01 mg/dL.
- Day 82 (ECOG 1): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.03 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 49.5 µmol/L; Calcium 2.23 mmol/L; Albumin 45 g/L; Total Protein 7.3 g/dL; Glucose 6.16 mmol/L.
- Day 152 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Lactate Dehydrogenase 4.12 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 1.94 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 51 ×10⁹/L; Creatinine 64.5 µmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 5.94 mmol/L.
- Day 266: M Protein 1.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.78 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 88 ×10⁹/L; Creatinine 61.9 µmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 5.61 mmol/L.
- Day 329 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 3.04 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 57.5 µmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.56 mmol/L.
- Day 427 (ECOG 0): M Protein 3.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.92 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 90.2 µmol/L; Calcium 2.45 mmol/L; Albumin 44 g/L; Total Protein 7.6 g/dL; Glucose 6.05 mmol/L.
- Day 525: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.92 mg/dL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.06 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 87.5 µmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L.
- Day 616: M Protein 6.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 18 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.89 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 91.9 µmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -23: Weight: 59 kg; Height: 151 cm.

Biospecimens (2 samples)
- Sample MMRF_2580_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_2580_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
